Somatic mutation profile of tumor specimen TCGA-V1-A9OT-01A (aliquot TCGA-V1-A9OT-01A-11D-A41K-08) from TCGA case TCGA-V1-A9OT, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9OT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd41d1b2-e6ec-4164-a954-ea0e49f96f1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9OT-10A (Blood Derived Normal), aliquot TCGA-V1-A9OT-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2190aa26-25d9-4c26-be92-1640a4e107b4

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH7A1 | c.1291C>G p.P431A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100778282, COSV63160957; called by muse, mutect2, varscan2
- DLX5 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.074); catalogued as COSV99756624, COSV99756729; called by muse, mutect2, varscan2
- DOK2 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV99374984; called by muse, mutect2, varscan2
- ESRP1 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64410340; called by muse, mutect2, varscan2
- EYA3 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs371072200, COSV100870301; called by muse, mutect2, varscan2
- KCNA6 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs781656226, COSV54974189, COSV54975172; called by muse, mutect2, varscan2
- KCNH7 | c.2761C>A p.Q921K | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as rs1221486185, COSV100150104, COSV59805653; called by muse, mutect2, varscan2
- KMT2C | c.2436G>A p.M812I | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100078110, COSV51504156; called by muse, varscan2
- LAPTM4B | c.433A>G p.N145D (on ENST00000445593; = p.N54D on NM_018407.6) | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101503509; called by muse, mutect2, varscan2
- MTUS1 | c.2536C>G p.P846A | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.099); catalogued as COSV100030139; called by muse, mutect2, varscan2
- MYOCD | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs531377746, COSV58500836; called by muse, mutect2, varscan2
- OAS2 | c.2127A>T p.R709S | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.109); catalogued as COSV100660331; called by muse, mutect2, varscan2
- SECISBP2L | c.2444G>A p.R815K (on ENST00000559471 / NM_001193489.2; = p.R770K on NM_014701.4) | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99961064; called by muse, mutect2, varscan2
- SEMA5A | c.2167G>A p.G723S | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as rs151007766; called by muse, mutect2, varscan2
- TLR2 | c.686T>C p.L229P | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99472580; called by muse, mutect2, varscan2
- PDCD11 | c.3457dup p.T1153Nfs*15 | Frame Shift Ins (INS) | VAF 32/92 reads (35%) | called by mutect2, pindel, varscan2
- PRAMEF8 | c.211A>C p.K71Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- PSD3 | c.2615_2623del p.D872_R874del (on ENST00000440756; = p.D871_R873del on NM_015310.4) | In Frame Del (DEL) | VAF 14/91 reads (15%) | called by mutect2, pindel, varscan2
- BTBD7 | c.3162C>T p.V1054= | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as COSV100598257; called by muse, mutect2, varscan2
- CDH4 | c.633C>T p.G211= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs527795069, COSV64647771; called by muse, mutect2, varscan2
- CPT2 | c.1893C>A p.R631= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV99598379; called by muse, mutect2, varscan2
- FAT1 | c.7041C>T p.T2347= | Silent (SNP) | VAF 64/162 reads (40%) | catalogued as COSV71675631; called by muse, mutect2, varscan2
- MPO | c.2007C>T p.F669= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99229476; called by muse, mutect2, varscan2
- MTUS2 | c.147C>T p.D49= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs183635259, COSV70917993; called by muse, mutect2, varscan2
- SYNPO | c.2628G>T p.L876= (on ENST00000394243 / NM_001166208.2; = p.L632= on NM_007286.6) | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs1300299406, COSV100302472, COSV56939121; called by muse, mutect2, varscan2
